Somatic mutation profile of tumor specimen TCGA-IN-A6RJ-01A (aliquot TCGA-IN-A6RJ-01A-21D-A33T-08) from TCGA case TCGA-IN-A6RJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 64.2 years (23,439 days).
Specimen TCGA-IN-A6RJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc3f71fc-ed2e-4550-98bc-e803573ee662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RJ-10A (Blood Derived Normal), aliquot TCGA-IN-A6RJ-10A-21D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/017db8eb-a921-414e-a8a3-ab043cffe6d7

The open-access MAF lists 121 somatic variants for this specimen: 83 protein-altering or splice-affecting, 37 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 37, Nonsense Mutation 4, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.6155G>A p.R2052K | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.793); catalogued as COSV100622574; called by muse, mutect2, varscan2
- AKAP6 | c.4368A>C p.E1456D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV55214326; called by muse, mutect2, varscan2
- ANK1 | c.5128G>A p.V1710I | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV99224564; called by muse, mutect2, varscan2
- ANKRD33 | c.116A>G p.Q39R (on ENST00000340970 / NM_001304459.2; = p.Q174R on NM_182608.4) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100001180; called by muse, mutect2
- APOB | c.2210A>T p.H737L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as COSV99264567; called by muse, mutect2, varscan2
- ARHGEF9 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1251027071, COSV99491568; called by muse, mutect2, varscan2
- ATP10A | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs759871370, COSV63523776; called by mutect2, varscan2
- BDNF | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV100151258; called by muse, mutect2
- BICC1 | c.2005T>G p.S669A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV54064547, COSV99570361; called by muse, mutect2
- CCKBR | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.146); catalogued as rs1372506488, COSV58102293; called by muse, mutect2, varscan2
- CCNA1 | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV99714429; called by muse, mutect2, varscan2
- CLCA2 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100991441; called by muse, mutect2
- CREBZF | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.013); catalogued as COSV99476170; called by muse, mutect2, varscan2
- CSMD3 | c.1753A>T p.K585* (on ENST00000297405 / NM_001363185.1; = p.K481* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99829193; called by muse, mutect2
- CST5 | c.423A>C p.K141N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100489584; called by muse, mutect2, varscan2
- CTNNA2 | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782637, COSV63546169; called by muse, varscan2
- DEFB115 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101269301; called by mutect2, varscan2
- EEF2 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58581191; called by muse, mutect2, varscan2
- EIF2AK3 | c.929T>G p.I310R | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100303575; called by muse, mutect2
- ELAVL2 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV99805742; called by muse, mutect2, varscan2
- EPB41L3 | c.3182A>G p.K1061R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100548420, COSV59461155; called by muse, mutect2, varscan2
- EPB41L3 | c.2697G>T p.E899D | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV100548423; called by muse, mutect2, varscan2
- ESF1 | c.1796A>C p.N599T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV99176299; called by muse, mutect2, varscan2
- FAM214A | c.1760A>C p.Q587P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.296); catalogued as COSV99957782; called by muse, mutect2, varscan2
- FAM71B | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261958; called by muse, mutect2, varscan2
- FAT4 | c.10520A>T p.D3507V | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627845; called by muse, mutect2, varscan2
- FLRT2 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV58135965; called by muse, mutect2, varscan2
- FLRT2 | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs771036586, COSV100420166; called by muse, mutect2, varscan2
- GSTA3 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99274469; called by muse, mutect2, varscan2
- HMCN1 | c.2158G>A p.V720I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs767575353, COSV54928730; called by muse, mutect2, varscan2
- HRNR | c.7168T>C p.S2390P | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1197859814, COSV100913173; called by mutect2, varscan2
- HS3ST3B1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100714485; called by muse, mutect2, varscan2
- HS6ST3 | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV100940206; called by muse, mutect2, varscan2
- IFNGR1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100880435; called by muse, mutect2, varscan2
- IGHG4 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201037000; called by muse, mutect2, varscan2
- IRS4 | c.2408A>G p.K803R | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV100929488; called by muse, mutect2, varscan2
- KIAA1109 | c.1858A>C p.T620P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV99150148; called by muse, mutect2, varscan2
- KRT16 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.053); catalogued as rs1383463670, COSV56968949; called by muse, mutect2
- KRT34 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748114147, COSV101222585; called by muse, mutect2, varscan2
- KSR2 | c.2012T>A p.L671H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV56682943, COSV56684819; called by muse, mutect2, varscan2
- LHX9 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100435721; called by muse, mutect2
- LRP1B | c.8767A>T p.R2923* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV101254426; called by muse, mutect2, varscan2
- LRRTM4 | c.202T>G p.L68V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101297473; called by muse, mutect2, varscan2
- MAGEC1 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV53571116; called by muse, mutect2, varscan2
- MAGEC3 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs751683228, COSV100025101; called by muse, mutect2, varscan2
- MED12L | c.1392A>C p.E464D | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.989); catalogued as COSV99852148; called by muse, mutect2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs776720499; called by mutect2, pindel, varscan2
- MOG | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.979); catalogued as COSV100972981; called by muse, mutect2
- MOGAT1 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101485108; called by muse, mutect2, varscan2
- MYT1L | c.3100T>G p.S1034A | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.033); catalogued as COSV101216964; called by muse, mutect2, varscan2
- NBAS | c.6998A>C p.H2333P | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1382241007, COSV99868209; called by muse, mutect2
- NPHS1 | c.3669C>A p.D1223E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.197); catalogued as COSV100799671; called by muse, mutect2, varscan2
- OR2M3 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV101513408; called by muse, mutect2, varscan2
- OR4D5 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58307110; called by muse, mutect2
- OR4N5 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100374063; called by muse, mutect2, varscan2
- OR4Q3 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59179726; called by muse, mutect2, varscan2
- PARP4 | c.985C>G p.P329A | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101131414; called by muse, mutect2
- PCDH15 | c.4694A>C p.K1565T (on ENST00000644397 / NM_001354429.2; = p.K1507T on NM_001142771.2) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100903536; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57299220, COSV57350026; called by muse, mutect2, varscan2
- PCDHB10 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99503959; called by muse, mutect2, varscan2
- PDE3A | c.2684A>T p.K895M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100761974; called by muse, mutect2, varscan2
- PHACTR3 | c.789T>A p.S263R | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV100732349; called by muse, mutect2
- PRAMEF18 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 64/505 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as rs1340287512; called by muse, mutect2, varscan2
- RGS18 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100817706, COSV66507928; called by muse, mutect2, varscan2
- SI | c.5012T>G p.F1671C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV100014644; called by muse, mutect2
- SLC39A12 | c.462A>C p.E154D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV101069928; called by muse, mutect2, varscan2
- SSX5 | c.192G>C p.K64N (on ENST00000347757 / NM_175723.1; = p.K105N on NM_021015.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100308599, COSV100308702; called by muse, mutect2, varscan2
- TNR | c.2020C>A p.Q674K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV99688537; called by muse, mutect2, varscan2
- TRAPPC8 | c.2816A>G p.N939S | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342549349, COSV99350805; called by muse, mutect2, varscan2
- TSHZ3 | c.3102G>T p.E1034D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99551021; called by muse, mutect2
- TTN | c.86285A>G p.N28762S (on ENST00000591111; = p.N21338S on NM_003319.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | PolyPhen probably damaging (0.994); catalogued as COSV100601642, COSV59874062; called by muse, mutect2
- TUT1 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV99545166; called by muse, mutect2
- UNC5D | c.1552T>A p.F518I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99773649; called by muse, mutect2, varscan2
- WDR83 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs764469932, COSV54418653; called by muse, mutect2, varscan2
- ZBTB40 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 17/182 reads (9%) | catalogued as COSV100988861; called by muse, mutect2
- ZBTB9 | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV101221736; called by muse, mutect2
- ZFYVE1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1185499113, COSV100606641; called by muse, mutect2, varscan2
- ZIM2 | c.1020A>C p.Q340H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55650716; called by muse, mutect2, varscan2
- ZNF100 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99973867; called by muse, mutect2, varscan2
- ZNF347 | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as COSV100498192; called by mutect2, varscan2
- ZNF536 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs867380993, COSV100834794, COSV100835275; called by mutect2, varscan2
- ZNF536 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs763225279, COSV62826124; called by muse, mutect2, varscan2
- TDRD6 | c.628_633del p.E210_R211del | In Frame Del (DEL) | VAF 15/136 reads (11%) | called by mutect2, pindel
- ACTB | c.669C>T p.F223= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs369943480, COSV59317081; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP10A | c.4062T>G p.S1354= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100791009, COSV63517382; called by muse, mutect2
- ATXN1 | c.1881C>T p.A627= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99785684; called by muse, mutect2, varscan2
- BICC1 | c.2370T>A p.T790= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV54067606, COSV99570366; called by muse, mutect2
- BIVM-ERCC5 | c.3996C>G p.L1332= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as rs1413143300; called by muse, mutect2
- BNC1 | c.426C>T p.Y142= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs745313602, COSV100597019; called by muse, mutect2, varscan2
- CACHD1 | c.747C>T p.D249= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1366339193, COSV51559602; called by muse, mutect2, varscan2
- CTNNA2 | c.1257A>G p.Q419= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV58157947, COSV58167835; called by muse, mutect2
- CYB5R1 | c.585C>A p.I195= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100924829; called by muse, mutect2, varscan2
- DISC1 | c.1233A>G p.Q411= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1401783421, COSV99697436; called by muse, mutect2, varscan2
- DMD | c.3477T>C p.T1159= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs893882584, COSV100818747, COSV63772565; called by muse, mutect2, varscan2
- EPHB6 | c.2490C>T p.A830= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100844200; called by muse, mutect2, varscan2
- FAM98A | c.1380T>C p.G460= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV99479142; called by muse, mutect2
- FGF14 | c.517T>C p.L173= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV101085326; called by muse, mutect2, varscan2
- FLG2 | c.843T>G p.G281= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV101165709; called by muse, mutect2, varscan2
- HSPD1 | c.1575G>C p.V525= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100798302; called by muse, mutect2, varscan2
- IGHMBP2 | c.321C>T p.T107= | Silent (SNP) | VAF 48/178 reads (27%) | catalogued as COSV99661944; called by muse, mutect2, varscan2
- IL1RAPL1 | c.679A>C p.R227= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56241048, COSV56251680; called by muse, mutect2, varscan2
- KIF6 | c.711A>G p.G237= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99758042; called by muse, mutect2, varscan2
- LRP12 | c.2529A>G p.E843= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99407413; called by muse, mutect2
- MFNG | c.336G>A p.A112= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs780589744, COSV63690154; called by muse, mutect2, varscan2
- NLRP9 | c.1848C>T p.L616= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs376696951, COSV60467612; called by muse, mutect2, varscan2
- NR1H4 | c.378G>A p.A126= (on ENST00000551379 / NM_001206993.2; = p.A116= on NM_005123.4) | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs767379406, COSV51849366, COSV51853756; called by muse, mutect2
- NUMA1 | c.1849C>T p.L617= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100705934; called by muse, mutect2, varscan2
- OR4K5 | c.225T>A p.S75= | Silent (SNP) | VAF 42/345 reads (12%) | catalogued as COSV100262245; called by muse, mutect2, varscan2
- OR5D16 | c.84C>T p.P28= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as rs767750812, COSV65722905; called by muse, mutect2
- OR8H3 | c.186T>C p.F62= | Silent (SNP) | VAF 73/436 reads (17%) | catalogued as COSV100538834; called by muse, mutect2, varscan2
- RB1 | c.483C>G p.L161= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99923845; called by muse, mutect2, varscan2
- RP1L1 | c.5508G>A p.E1836= | Silent (SNP) | VAF 26/258 reads (10%) | catalogued as COSV101223075; called by muse, mutect2, varscan2
- SEMA6A | c.1209C>T p.P403= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1244355024, COSV99145616; called by muse, mutect2, varscan2
- SERPINI1 | c.438C>G p.A146= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99854931; called by muse, mutect2, varscan2
- SI | c.3499T>C p.L1167= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100014645, COSV52303947; called by muse, mutect2
- SLC10A6 | c.348C>T p.T116= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV56721961; called by muse, mutect2, varscan2
- SLC39A12 | c.150C>G p.L50= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV101069926; called by muse, mutect2
- SYMPK | c.825C>A p.I275= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99841516; called by muse, mutect2, varscan2
- TTLL12 | c.1066C>T p.L356= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99333294; called by muse, mutect2, varscan2
- WDR83 | c.309C>A p.R103= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV99663805; called by muse, mutect2, varscan2
- ELMO1 | c.1438-24348G>A | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100163840; called by muse, mutect2, varscan2
